Surgical pathology report (de-identified scan), TCGA case TCGA-58-A46M, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-A46M-01A (Primary Tumor).

Pathology Report-Summary:

Material:

Lung, left, lower lobe: 19.0 x 14.0 x 6.0 cm

tumor: 5.1 x 3.2 x 2.6 cm

Diagnosis:

Squamous Cell Carcinoma, (NOS)

Infiltration of pleura visceralis

pT2b, pN1 (2/33), pMx, G3

Pathologist:

ICD-O-3

Carcinoma, Squamous Cell, NOS

8070/3

Site: lung, lower lobe

C34.3

9-5-12
RD

W
8/21/12

Source: NCI Genomic Data Commons file 914b82f8-db08-4851-8744-d2fceb337df3 (TCGA-58-A46M.29B1DF65-6310-4E01-9CBF-7678678A7D38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).